Surgical pathology report (de-identified scan), TCGA case TCGA-57-1582, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site International Genomics Consortium, specimen TCGA-57-1582-01A (Primary Tumor).

[page 1 of 3]
TCGA-57-1582

Result Name	Results	Units	Reference Range
☒ Surgical Pathology	COPY TO:		

COPY TO:

IO Consultation

Frozen Section Diagnosis: "Large cell carcinoma"

Performed by Dr. [REDACTED] Campus

Pre-Op Diagnosis

Pelvic mass

Post-Op Diagnosis

Ovarian cancer

Clinical History

Nothing indicated on requisition

Gross Description:

Ten parts

Container labeled [REDACTED] 1 - cervix, uterus, tubes and ovaries" is a previously laterally sectioned uterus with attached cervix and bilateral adnexa. The uterus and cervix together weigh 132 grams and on reconstruction measure approximately 9.9 x 6.0 x 5.6 cm. The cervix has a wrinkled tan pink ectocervical mucosa. The os is patent. The uterine canal sounds to a depth of 7.4 cm. The endocervical canal is lined by trabeculated tan mucosa. The uterine serosa is smooth and pink red with several marginally located nodular areas of rubbery to fleshy tan gray to pink tissue measuring up to 1.5 cm. These are noted on both the anterior and posterior peritoneal reflections. The myometrium measures up to 2.2 cm and is tan pink and trabecular with the presence of an intramural 3.1 cm well defined tan fibrous nodule with a bulging whorled tan fibrotic cut surface noted in the upper posterior region extending to the fundus. The endometrial canal is lined by up to 0.3 cm of smooth edematous tan pink mucosa. No gross lesions are identified.

The left fallopian tube measures 5.4 x 0.7 x 0.7 cm and has a smooth pink red serosa. On sectioning there is an edematous tan wall with a pinpoint lumen. Noted in the mesosalpingeal soft tissue extending to the round ligament are several similar nodules of tan gray fleshy to fibrotic tissue measuring up to 2.0 cm. The left ovary measures 5.2 x 3.9 x 3.6 cm and has a lobulated tan pink outer surface with several adherent nodular and plaque-like areas of similar fibrotic tissue up to 3.0 cm in greatest dimension. On sectioning there is a previously opened 3.1 cm cystic structure with a smooth inner lining containing clotted blood. The remaining parenchyma is edematous, mottled gray tan, and fibrotic.

The right fallopian tube measures 6.4 x 0.6 x 0.6 cm and has a mostly smooth congested serosa. At the fimbriated end there is an adherent 1.6 cm nodule with similar fleshy to fibrotic tissue. On sectioning the tube has an edematous tan wall with a pinpoint lumen. The mesosalpingeal and para-ovarian soft tissue shows several similar nodules up to 1.3 cm. The right ovary measures 4.5 x 2.9 x 2.6 cm and has a lobular tan pink outer surface with multiple adherent plaques and nodules of similar lesional tissue measuring up to 1.2 cm. This extends over approximately 50-60% of the ovarian surface. On sectioning the uninvolved parenchyma is mottled, edematous, tan pink, and fibrotic appearing.

Also received in the same container is a 4.1 x 3.1 x 2.5 cm nodular portion of similar lesional tissue with a fleshy to gritty gray tan fibrotic cut surface. This is received along with 4.0 x 2.9 x 1.2 cm of similar irregular tissue fragments. The portion submitted for frozen section is reported as "large cell carcinoma" by [REDACTED]

Also received in the same container are three tissue cassettes each labeled [REDACTED]. The frozen residue is submitted labeled "A." Representative sections of the remaining tissue are submitted labeled as follows: B - anterior cervix; C - posterior cervix; D - lower uterine segment and shaved posterior serosa; E - representative anterior peritoneal reflection; F - representative posterior peritoneal reflection; G - representative posterior intramural nodule; H and I - full thickness anterior endomyometrium; J -

Path stage: T3 N1 Mx

[page 2 of 3]
posterior endometriometrium; K - left fallopian tube and surrounding tissue; L and M - representative left ovary; N - right fallopian tube and surrounding soft tissue; O and P - representative right ovary; Q and R - representative separate tissue nodules.

Container labeled "2 - left pelvic sidewall" is a 7.2 x 2.5 x 2.3 cm elongated portion of fleshy to fibrotic gray tan to pink tissue with gray tan to pink fleshy to fibrotic cut surface. This is received along with 4.5 x 2.6 x 1.5 cm of similar nodular and irregular tissue fragments. Representative sections of the larger fragments are submitted in three cassettes.

Container labeled "3 - right pelvic sidewall" is a 5.0 x 5.0 x 2.6 cm of soft shaggy focally nodular appearing gray tan to pink fleshy to fibrotic tissue fragments with fleshy to fibrotic tan pink cut surfaces. Representative sections of the larger fragments are submitted in three cassettes.

Container labeled "4 - pelvic tumor" are three irregular fragments of soft rubbery shaggy gray pink to brown tissue measuring from 0.9 to 2.5 cm in greatest dimension each and measuring in aggregate 3.0 x 2.8 x 1.1 cm. On sectioning these have fleshy to fibrotic gray tan cut surfaces. Representative sections are submitted in a single cassette.

Container labeled "5 - right pelvic lymph node" are four nodular portions of rubbery tan pink fibrotic tissue from 1.0 to 2.5 cm in greatest dimension each. On sectioning each of these nodules has a slightly gritty fleshy to fibrotic appearing cut surface. These are received along with a 3.0 x 2.0 x 1.0 cm portion of pink yellow fibroadipose tissue which on palpation and sectioning reveal a few poorly defined nodular areas of similar tissue measuring up to 0.8 cm in greatest dimension each. Representative sections of the four largest nodules are submitted labeled "A and B" while the smaller nodules are submitted labeled "C."

Container labeled "6 - right aortic node" are two nodular portions of rubbery gray tan to pink tissue 2.0 and 2.8 cm in greatest dimension. On sectioning each has a fleshy to fibrotic gray tan to pink cut surface. Representative sections of each nodule is submitted in a single cassette.

Container labeled "7 - right sigmoid colon biopsy" are three nodular portions of rubbery tan gray to pink fleshy to fibrotic tissue each of which is surrounded by yellow adipose tissue. The nodules measure from 1.0 to 1.6 cm in greatest dimension each.

On sectioning the nodules have a fleshy to fibrotic gray tan cut surface. Representative sections of the nodules are submitted in two cassettes.

Container labeled "8 - appendix" is a 5.3 x 0.6 x 0.6 cm vermiform appendix with a moderate amount of attached mesoappendix. The serosa is smooth and tan pink while the wall is fleshy and fibrotic with the lumen up to 0.3 cm containing a small amount of semi-fluid gray brown fecal material. Noted at the distal tip on the mesoappendix is a 0.3 cm nodule of gray tan fibrotic appearing tissue. No other gross lesions are identified. Representative sections are submitted in a single cassette.

Container labeled "9 - left pelvic lymph node" is a 1.5 x 1.0 x 0.4 cm nodular portion of fleshy to fibrotic tan gray to pink tissue with a mottled tan gray to pink fleshy and fibrotic appearing cut surface. The bisected nodule is entirely submitted in a single cassette.

Container labeled "10 - omentum" is a 60.0 x 14.5 x up to 2.2 cm sheet of pink yellow vascularized fibroadipose tissue which on palpation and sectioning reveals several thin delicate congested fibrous adhesions as well as several embedded and adherent tan gray fibrotic nodules with fleshy to fibrotic slightly gritty tan gray cut surfaces. These measure up to 2.6 cm in greatest dimension and occupy approximately 5% of the total specimen mass. Representative sections are submitted in five cassettes.

Microscopic Description:

Slides are reviewed labeled

Final Diagnosis

Cervix, uterus, tubes and ovaries:

Benign ectocervical squamous mucosa.

Benign endocervical mucosa with squamous metaplasia and small Nabothian cysts.

Serosal surface demonstrating metastatic adenocarcinoma (see below).

Lower uterine segment demonstrating lymphatic spread of papillary adenocarcinoma

into the wall of the lower uterine segment.

Anterior and posterior peritoneal reflection demonstrating metastatic papillary

adenocarcinoma.

Secretory phase endometrium, day 17, without hyperplasia nor atypia.

Myometrium with metastatic papillary adenocarcinoma within intravascular luminal and

perineural invasion.

Mural leiomyomata.

[page 3 of 3]
Left and right fallopian tubes and ovaries:
Bilateral peritubal and intraluminal metastatic papillary adenocarcinoma.
Papillary serous adenocarcinoma.
Grade: 3.
Location: Bilateral ovaries are involved with at least 50% of the ovarian parenchyma involved by neoplasm.
Lymphovascular space invasion: Present.
Right and left fallopian tubes: See above.
Omentum: See specimen #10 below.
Other peritoneal biopsies: See below. [REDACTED]
Hemorrhagic corpus luteum cyst (left): Simple follicular cyst, right ovary.
Lymph node status: See specimens #5, 6, and 9 below.
The frozen section diagnosis above is confirmed on permanent sections. [REDACTED]
Left pelvic sidewall:
Metastatic papillary serous adenocarcinoma.
Lymph node with 80% involvement by metastatic adenocarcinoma. [REDACTED]
Right pelvic sidewall:
Metastatic papillary serous adenocarcinoma. [REDACTED]
Pelvic tumor:
Papillary serous adenocarcinoma. [REDACTED]
Right pelvic lymph node:
Total number of lymph nodes examined: 4.
Total number of lymph nodes containing metastatic carcinoma: 4.
Size of the largest lymph node: 2.3 x 1.5 cm based on direct measurement from the glass slide. [REDACTED]
Right aortic node:
Total number of lymph nodes examined: 2.
Total number of lymph nodes containing metastatic carcinoma: 2.
Size of the largest lymph node: 1.9 x 1.3 cm based on the direct measurement from the glass slide. [REDACTED]
Right sigmoid colon biopsy:
Metastatic papillary serous adenocarcinoma.
Trichrome stain reveals focal increase in collagen deposition. [REDACTED]

Appendix:

Benign vermiform appendix.
Periappendiceal metastatic papillary serous adenocarcinoma. [REDACTED]
Left pelvic lymph node:
Total number of lymph nodes examined: 1.
Total number of lymph nodes containing metastatic carcinoma: 1.
Size of the lymph node: 1.5 x 0.7 cm based on direct measurement from the glass slide. [REDACTED]
Omentum:
Adipose tissue with multiple nodules of metastatic papillary serous adenocarcinoma.
[REDACTED]

Stage: pT3N1MX.

Comments

It should be noted that the vast majority of the ovarian lesions appear to be on the left side with the predominance of the right sided tumor on the surface of the ovary. However, both ovaries do demonstrate the presence of papillary serous adenocarcinoma. Psammoma bodies are found in both the primary sites and the metastatic sites.
This test has been finalized at the [REDACTED] Campus.
[REDACTED]

Source: NCI Genomic Data Commons file 67b2356f-95a7-45f1-aec2-489f048233cf (TCGA-57-1582.0ED35510-C6AD-416B-8B57-E97005471DC1.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).